Somatic mutation profile of tumor specimen TARGET-30-PAITCI-01A (aliquot TARGET-30-PAITCI-01A-01W) from TARGET case TARGET-30-PAITCI, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Age at diagnosis: 2.0 years (728 days).
Specimen TARGET-30-PAITCI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b079731-41b1-4a54-8161-512237777959.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAITCI-10A (Blood Derived Normal), aliquot TARGET-30-PAITCI-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a54f149-6931-4f3c-b4d1-0fb61877a45e

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREB5 | c.1126G>A p.E376K (on ENST00000357727 / NM_182898.4; = p.E369K on NM_004904.3) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1479869837, COSV63225963; called by muse, mutect2, varscan2
- DNASE1L1 | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV50010922; called by muse, mutect2, varscan2
- IGSF11 | c.809G>C p.S270T (on ENST00000393775 / NM_001015887.3; = p.S269T on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/388 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV61174880; called by muse, mutect2, varscan2
- MTARC2 | c.476A>G p.D159G | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs1308891684, COSV63766231; called by muse, mutect2, varscan2
- ST18 | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 39/269 reads (14%) | catalogued as COSV52505173, COSV52512181; called by muse, mutect2, varscan2
- ZNF133 | c.1537C>G p.Q513E (on ENST00000316358 / NM_001352454.2; = p.Q512E on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV100315526; called by muse, mutect2
- PDGFRB | c.2779G>T p.A927S | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.059); called by muse, mutect2
- ABCC6 | c.3729C>G p.P1243= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV52742044, COSV52746866; called by muse, mutect2, varscan2
- CSMD3 | c.774T>C p.P258= | Silent (SNP) | VAF 34/249 reads (14%) | catalogued as COSV52280580; called by muse, mutect2, varscan2
- MSH2 | c.801T>A p.V267= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV51883391, COSV99253401; called by muse, mutect2, varscan2
